Surgical pathology report (de-identified scan), TCGA case TCGA-86-A4D0, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-A4D0-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Lung

Tumor size: 6 x 6 x 6 cm

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Visceral pleura

Other tumor nodules: Not specified

Lymph nodes: 0/6 positive for metastasis (Regional 0/6)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: CK7, CD15, TTF-1 positive; CK10, P63 negative

Comments: Right- upper

1CD-0-3

Adenocarcinoma, NOS 814013

Site: Lung, Upper lobe C34.1

fw
9/24/12

Metastatic History		X

Source: NCI Genomic Data Commons file 11b7eb2d-d567-4e11-af44-f9e8c8625d2c (TCGA-86-A4D0.80C129A3-A5B6-4B1C-9979-44A307867744.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).